Surgical pathology report (de-identified scan), TCGA case TCGA-B4-5836, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Cureline, specimen TCGA-B4-5836-01A (Primary Tumor).

[page 1 of 4]
Index	Specimen label	Clinical Site #	Case #	Ethnicity (Race)	Clinical Diagnosis	DOB (mm/dd/yyyy)	Sex	Date of procurement
1					Renal Cancer			
				)	Renal Cancer			

[page 2 of 4]
Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container	Unit
Kidney, right	Primary	Tumor	Tissue	Frozen	cryomold	1	280	mg
Blood	n/a	normal	Blood	Frozen	tube	1	4	ml

[page 3 of 4]
Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Prior Chemo / Hormonal Th	Chemo / Horm Th Details	Prior Radiation
Surgery	Renal cell carcinoma	2	no data	no data	no data	no	no	no
Blood draw	n/a	n/a	n/a	n/a	n/a	no	no	no

[page 4 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

Cellular Tumor %
90
n/a

Source: NCI Genomic Data Commons file 7fa02bea-8d80-4f89-8cf3-3a151a2d36f0 (TCGA-B4-5836.F39308E8-58C1-4AA8-BFD2-0070CE2B10CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).